Somatic mutation profile of tumor specimen C3L-02130-01 (aliquot CPT0130030009) from CPTAC case C3L-02130, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.9 years (25,907 days).
Specimen C3L-02130-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b97388eb-9a98-4a64-8bb6-343cb9e0ce5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02130-31 (Blood Derived Normal), aliquot CPT0130150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af392702-af6b-4548-a9ac-004198ad6819

The open-access MAF lists 416 somatic variants for this specimen: 287 protein-altering or splice-affecting, 69 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 240, Silent 69, Intron 24, Frame Shift Del 17, Nonsense Mutation 14, RNA 12, 3'UTR 10, Splice Site 9, 5'UTR 8, 5'Flank 5, Splice Region 5, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 38/152 reads (25%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- ADAMTS20 | c.229C>G p.R77G | Missense Mutation (SNP) | VAF 58/494 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV67129951; called by muse, mutect2, varscan2
- ADARB2 | c.1760del p.G587Afs*13 | Frame Shift Del (DEL) | VAF 59/419 reads (14%) | catalogued as COSV67181960; called by mutect2, pindel, varscan2
- ANKRD30A | c.1995G>C p.L665F (on ENST00000611781; = p.L609F on NM_052997.2) | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV64610751; called by muse, mutect2, varscan2
- APBB1IP | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1190364023; called by muse, mutect2, varscan2
- BPI | c.893G>T p.G298V (on ENST00000262865; = p.G294V on NM_001725.3) | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV99480522; called by muse, mutect2, varscan2
- C10orf71 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 28/475 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs369285936; called by muse, mutect2
- C10orf71 | c.3389C>G p.S1130W | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as COSV60506084; called by muse, mutect2, varscan2
- C8A | c.1166A>G p.N389S | Missense Mutation (SNP) | VAF 78/603 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs1318586861; called by muse, mutect2, varscan2
- CD101 | c.2963G>T p.R988L | Missense Mutation (SNP) | VAF 49/706 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs745725092; called by muse, mutect2
- CD14 | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs757258287; called by muse, mutect2, varscan2
- CDC5L | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs550214338, COSV65176597; called by muse, mutect2, varscan2
- CDH10 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV52574737, COSV52577488; called by muse, mutect2, varscan2
- CDH18 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV56957699, COSV56962750; called by mutect2, varscan2
- CECR2 | c.1481G>A p.C494Y (on ENST00000342247 / NM_001290047.2; = p.C311Y on NM_001290046.1) | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1206729717; called by muse, mutect2, varscan2
- CKAP5 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs771781888; called by muse, mutect2, varscan2
- CSMD1 | c.4580C>A p.A1527D (on ENST00000520002; = p.A1526D on NM_033225.6) | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59296859; called by muse, mutect2, varscan2
- CSPG4 | c.3023G>T p.R1008L | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57902345; called by muse, mutect2, varscan2
- CYRIA | c.827C>A p.S276Y | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62867151; called by muse, mutect2, varscan2
- DCANP1 | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV72345763, COSV72345947; called by muse, mutect2
- DCSTAMP | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.311); catalogued as COSV52578865; called by muse, mutect2, varscan2
- DIDO1 | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1156445980; called by muse, mutect2, varscan2
- ERICH3 | c.3753C>A p.C1251* | Nonsense Mutation (SNP) | VAF 68/332 reads (20%) | catalogued as COSV58619418; called by muse, mutect2, varscan2
- ESR1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV52782951; called by muse, mutect2
- EYA2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs1401120261, COSV57947672; called by muse, mutect2, varscan2
- FAM135B | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs762951590, COSV52731330; called by muse, mutect2, varscan2
- FGF14 | c.408A>G p.S136= | Splice Region (SNP) | VAF 96/535 reads (18%) | catalogued as COSV65957579; called by muse, mutect2, varscan2
- G6PC2 | c.621C>A p.Y207* | Nonsense Mutation (SNP) | VAF 26/360 reads (7%) | catalogued as rs779851185; called by muse, mutect2
- GABPB2 | c.824T>C p.I275T | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs764627399, COSV99071339; called by muse, mutect2, varscan2
- GAD1 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 37/545 reads (7%) | catalogued as rs79569021; called by muse, mutect2
- GIMAP2 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56234925; called by muse, mutect2, varscan2
- GRIK2 | c.2305C>A p.P769T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752458928, COSV59738476, COSV59773466; called by muse, varscan2
- HLA-C | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 47/618 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs281860346; called by muse, mutect2
- HYDIN | c.5565C>A p.F1855L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99991915; called by mutect2, varscan2
- IGHV3-49 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 163/598 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.061); catalogued as rs782371716; called by muse, mutect2, varscan2
- INTS13 | c.1372T>C p.Y458H | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1241259550; called by muse, mutect2, varscan2
- KLHL14 | c.1286T>C p.I429T | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as rs757247031; called by muse, mutect2, varscan2
- KRT33A | c.1037G>T p.R346L | Missense Mutation (SNP) | VAF 73/550 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99144995; called by muse, mutect2, varscan2
- LCE1E | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as rs568326067; called by muse, mutect2, varscan2
- LCNL1 | c.348del p.F116Lfs*93 | Frame Shift Del (DEL) | VAF 42/270 reads (16%) | catalogued as COSV56401369; called by mutect2, pindel, varscan2
- LRFN5 | c.1683C>A p.H561Q | Missense Mutation (SNP) | VAF 117/595 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV53252102, COSV99986004; called by muse, mutect2, varscan2
- LRRC31 | c.458G>T p.R153I | Missense Mutation (SNP) | VAF 66/841 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52980313; called by muse, mutect2
- MAP3K11 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as rs995731687; called by muse, mutect2
- MKRN3 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 36/391 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1263142497; called by muse, mutect2
- MPRIP | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 82/269 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs370517552; called by muse, mutect2, varscan2
- MRC2 | c.2266G>T p.G756C | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as rs1240518386, COSV100316873; called by muse, mutect2
- MS4A1 | c.619G>C p.V207L | Missense Mutation (SNP) | VAF 94/659 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV61941865; called by muse, mutect2, varscan2
- MYO16 | c.550G>T p.G184* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV99193811; called by muse, mutect2, varscan2
- NEFH | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 46/743 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as rs377149236; called by muse, mutect2
- NGF | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV65688684; called by muse, mutect2
- NOD2 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 32/538 reads (6%) | catalogued as rs760623178, COSV56053773; called by muse, mutect2
- NOTCH3 | c.1378+1G>A p.X460_splice | Splice Site (SNP) | VAF 22/186 reads (12%) | catalogued as rs1324664338; called by muse, mutect2, varscan2
- NPAP1 | c.1897C>G p.P633A | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1202533123; called by muse, mutect2, varscan2
- NT5C3B | c.402C>T p.L134= | Splice Region (SNP) | VAF 23/175 reads (13%) | catalogued as rs1555618902; called by muse, mutect2, varscan2
- NTRK1 | c.1859G>A p.G620D | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV62327175; called by muse, mutect2, varscan2
- OBSCN | c.14008G>A p.E4670K | Missense Mutation (SNP) | VAF 39/860 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs758892825, COSV52769509; called by muse, mutect2
- OPCML | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59422560; called by muse, mutect2, varscan2
- OR11L1 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.158); catalogued as COSV63315401; called by muse, mutect2, varscan2
- OR14A2 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63573373; called by muse, mutect2, varscan2
- OR2M5 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 72/549 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs758280431, COSV63547168; called by muse, mutect2, varscan2
- OR4K2 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 52/948 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53849356; called by muse, mutect2
- OR4Q3 | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 37/785 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.121); catalogued as COSV59178657; called by muse, mutect2
- OR4X2 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1225433193, COSV56583468; called by muse, mutect2, varscan2
- OTOG | c.5884G>A p.E1962K | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs866767745; called by muse, mutect2, varscan2
- PATE2 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62069084; called by muse, mutect2, varscan2
- PAX1 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1380192911; called by muse, varscan2
- PDCD5 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs756164730, COSV55678530; called by muse, mutect2, varscan2
- PDGFRA | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.48); catalogued as COSV57267737; called by muse, mutect2
- PER1 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs979086054; called by muse, mutect2
- PIEZO2 | c.7016G>T p.R2339L | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99555018; called by muse, mutect2, varscan2
- PLEC | c.12103G>C p.V4035L (on ENST00000322810 / NM_201380.4; = p.V3925L on NM_000445.5) | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs781968312; called by muse, mutect2
- PTPRC | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV61408930; called by muse, mutect2
- RP1L1 | c.1293C>G p.H431Q | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.579); catalogued as COSV66756535; called by muse, mutect2
- RPS6KB1 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.37); catalogued as rs779532384; called by muse, mutect2
- RYR3 | c.6356T>A p.L2119Q | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1351196408; called by muse, mutect2, varscan2
- SAMD9 | c.3938C>A p.S1313* | Nonsense Mutation (SNP) | VAF 82/476 reads (17%) | catalogued as COSV66077075; called by muse, mutect2, varscan2
- SCN10A | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 53/487 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71862756; called by muse, mutect2, varscan2
- SEMA4F | c.303C>G p.D101E | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.044); catalogued as rs769779196; called by muse, mutect2, varscan2
- SFMBT1 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); catalogued as COSV56254331; called by muse, mutect2, varscan2
- SHANK2 | c.4659G>T p.K1553N | Missense Mutation (SNP) | VAF 915/1655 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53621049; called by muse, mutect2, varscan2
- SHPRH | c.1815C>A p.S605R | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV51619425; called by muse, mutect2, varscan2
- SIGLEC1 | c.3460C>T p.P1154S | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV52468988, COSV99170896; called by muse, mutect2, varscan2
- SLC39A14 | c.835A>C p.N279H | Missense Mutation (SNP) | VAF 16/223 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1044623449; called by muse, mutect2
- SLC40A1 | c.387+1G>T p.X129_splice | Splice Site (SNP) | VAF 17/366 reads (5%) | catalogued as COSV99656410; called by muse, mutect2
- SPTA1 | c.6830G>A p.S2277N | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs767549869, COSV63758655; called by muse, mutect2, varscan2
- SSTR4 | c.612C>A p.H204Q | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99658676; called by muse, mutect2, varscan2
- SUMF1 | c.603-2A>T p.X201_splice | Splice Site (SNP) | VAF 68/389 reads (17%) | catalogued as CD031567, CS124847; called by muse, mutect2, varscan2
- SYNE1 | c.15718del p.E5240Rfs*9 (on ENST00000367255 / NM_182961.4; = p.E5169Rfs*9 on NM_033071.3) | Frame Shift Del (DEL) | VAF 57/475 reads (12%) | catalogued as COSV99573870; called by mutect2, pindel, varscan2
- SYNM | c.4567C>T p.Q1523* (on ENST00000336292 / NM_145728.3; = p.Q1211* on NM_015286.6) | Nonsense Mutation (SNP) | VAF 51/429 reads (12%) | catalogued as rs782472976, COSV50441176; called by muse, mutect2, varscan2
- TEAD2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1363440759, COSV60872752; called by muse, mutect2
- TECTA | c.6121G>C p.A2041P | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.486); catalogued as COSV50838606; called by muse, varscan2
- TET3 | c.4628A>G p.N1543S | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs778464349; called by muse, mutect2, varscan2
- TLL2 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63575974; called by muse, mutect2, varscan2
- TMEM253 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757512802; called by muse, mutect2, varscan2
- TNNI3 | c.235C>A p.R79S | Missense Mutation (SNP) | VAF 94/598 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.727); catalogued as rs3729712, CM1511464; called by muse, mutect2, varscan2
- TP53 | c.837del p.R280Efs*65 | Frame Shift Del (DEL) | VAF 230/902 reads (25%) | catalogued as CD963012, COSV53098982, COSV53696473; called by mutect2, pindel, varscan2
- ZFHX4 | c.6965C>G p.P2322R | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV50571317; called by muse, mutect2, varscan2
- ZFP28 | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.32); catalogued as COSV56735914; called by muse, mutect2
- ZIC4 | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV67171332; called by muse, mutect2
- ZNF536 | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 102/449 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.719); catalogued as COSV62828018, COSV62831316; called by muse, mutect2, varscan2
- ZNF565 | c.124G>T p.A42S (on ENST00000355114; = p.A2S on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/248 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as COSV58411017; called by muse, mutect2, varscan2
- ZNF681 | c.1269del p.Q423Hfs*132 | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | catalogued as COSV68075527; called by pindel, varscan2
- ZNF831 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs377099862, COSV100926333; called by muse, mutect2, varscan2
- ACP7 | c.1273G>T p.V425F | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS16 | c.3197C>A p.T1066K | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ANKEF1 | c.1340A>G p.Q447R | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD36 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- AP2A1 | c.28A>T p.M10L | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- APOB | c.5777A>T p.Q1926L | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- ARHGAP9 | c.1532G>T p.R511L (on ENST00000393797 / NM_001319850.2; = p.R492L on NM_032496.4) | Missense Mutation (SNP) | VAF 52/421 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGEF4 | c.1816G>C p.E606Q | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP10A | c.4057C>G p.P1353A | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10B | c.3089C>A p.S1030Y | Missense Mutation (SNP) | VAF 33/260 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- BCL11A | c.2033G>A p.G678E (on ENST00000335712 / NM_001365609.1; = p.G712E on NM_018014.4) | Missense Mutation (SNP) | VAF 20/287 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- BMP3 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BSX | c.390G>C p.E130D | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); called by muse, mutect2
- BTK | c.1452C>A p.N484K | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- C12orf29 | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 59/429 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- C2CD5 | c.2527G>C p.A843P | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf54 | c.3319G>C p.D1107H | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNA1C | c.2461-1G>T p.X821_splice | Splice Site (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- CALHM6 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- CAPN13 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 73/596 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CD22 | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CDX2 | c.681G>T p.E227D | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CFHR1 | c.59-2A>T p.X20_splice | Splice Site (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- CHRNB3 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 43/288 reads (15%) | called by muse, mutect2, varscan2
- CLK3 | c.475G>A p.E159K (on ENST00000395066 / NM_001130028.1; = p.E11K on NM_003992.4) | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL11A2 | c.2201A>G p.H734R (on ENST00000341947 / NM_080680.3; = p.H627R on NM_080679.2) | Missense Mutation (SNP) | VAF 61/701 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.684); called by muse, mutect2
- COL28A1 | c.1583G>C p.G528A | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CR1 | c.318T>G p.N106K | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CUBN | c.2275A>T p.S759C | Missense Mutation (SNP) | VAF 58/498 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CYP2E1 | c.175C>A p.R59= | Splice Region (SNP) | VAF 24/139 reads (17%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DGKB | c.2001G>T p.M667I | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DLGAP2 | c.2506del p.Q836Kfs*21 | Frame Shift Del (DEL) | VAF 26/260 reads (10%) | called by mutect2, pindel
- DNAH7 | c.10664A>T p.Y3555F | Missense Mutation (SNP) | VAF 27/458 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.107); called by muse, mutect2
- DNAJC16 | c.1599G>T p.W533C | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DPP6 | c.833C>A p.T278N (on ENST00000377770 / NM_001364500.2; = p.T216N on NM_001936.5) | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DYSF | c.1790C>A p.A597D | Missense Mutation (SNP) | VAF 88/653 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- DZIP1L | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 134/680 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EIF4G2 | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.975); called by muse, mutect2
- EPS8 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2
- F13A1 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.048); called by muse, mutect2
- FAM155B | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM71E2 | c.860C>A p.T287N | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2
- FGB | c.1332_1333del p.R445Ifs*18 | Frame Shift Del (DEL) | VAF 53/499 reads (11%) | called by mutect2, pindel, varscan2
- FILIP1 | c.1786C>G p.L596V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GMPS | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 42/287 reads (15%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.926T>C p.M309T | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIN3A | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 131/712 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GUSB | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GYPC | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 93/642 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HABP4 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.235); called by muse, mutect2
- HCAR2 | c.280A>C p.K94Q | Missense Mutation (SNP) | VAF 88/761 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- HEPACAM2 | c.305C>A p.P102Q (on ENST00000394468 / NM_001039372.4; = p.P90Q on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/461 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- HERC5 | c.1481C>A p.P494Q | Missense Mutation (SNP) | VAF 43/339 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HSD17B7 | c.904-2A>G p.X302_splice | Splice Site (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- HYDIN | c.5566C>A p.P1856T | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHD | c.1225A>T p.T409S | Missense Mutation (SNP) | VAF 122/677 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGKV1-27 | c.250T>A p.F84I | Missense Mutation (SNP) | VAF 30/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- IPO7 | c.334_336del p.T112del | In Frame Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- KDM3A | c.1801G>C p.G601R | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KPNA1 | c.645del p.L216Ffs*11 | Frame Shift Del (DEL) | VAF 43/272 reads (16%) | called by mutect2, pindel, varscan2
- KRTAP10-11 | c.522C>G p.C174W | Missense Mutation (SNP) | VAF 84/775 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRCH1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- LRRIQ1 | c.4919G>T p.G1640V | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MAEL | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MALRD1 | c.3316G>A p.V1106I | Missense Mutation (SNP) | VAF 15/179 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- MAN2A2 | c.540G>C p.W180C | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCAM | c.1643C>A p.T548K | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2
- MCM5 | c.1591A>G p.M531V | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCMDC2 | c.1330del p.E444Rfs*7 | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | called by mutect2, pindel, varscan2
- MGAT4D | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- MGAT4D | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.092); called by muse, mutect2
- MMP8 | c.1147T>A p.Y383N | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.017); called by muse, mutect2
- MOB1B | c.620T>A p.L207Q | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MROH5 | c.428T>G p.F143C | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- MS4A14 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.29); called by muse, mutect2
- MTMR12 | c.884G>C p.S295T | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYO9A | c.7031A>G p.Q2344R | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- MYO9A | c.6869C>T p.P2290L | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEUROG1 | c.707A>C p.Y236S | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAIN4 | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKX2-2 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- NLRP4 | c.439C>A p.Q147K | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPBWR1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NRXN2 | c.2930A>G p.Y977C | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OCA2 | c.2079G>C p.E693D | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- OLFM1 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ONECUT1 | c.1201C>A p.H401N | Missense Mutation (SNP) | VAF 50/474 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR2G3 | c.476A>G p.H159R | Missense Mutation (SNP) | VAF 23/337 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2
- OR4S2 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 10/231 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2
- OR52E8 | c.485T>A p.V162D | Missense Mutation (SNP) | VAF 43/254 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- OR5AS1 | c.578A>T p.Q193L | Missense Mutation (SNP) | VAF 171/388 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.2840C>A p.P947H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- OXSM | c.1196C>G p.T399R | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- P2RX1 | c.1070T>C p.L357P | Missense Mutation (SNP) | VAF 149/491 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC5 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PARD3 | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH11Y | c.3988G>T p.G1330C | Missense Mutation (SNP) | VAF 9/260 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHB12 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA7 | c.172del p.E58Sfs*20 | Frame Shift Del (DEL) | VAF 28/229 reads (12%) | called by mutect2, pindel, varscan2
- PCNX2 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDGFRA | c.177C>A p.Y59* | Nonsense Mutation (SNP) | VAF 48/390 reads (12%) | called by muse, mutect2, varscan2
- PDZRN4 | c.2844G>T p.Q948H (on ENST00000402685 / NM_001164595.2; = p.Q690H on NM_013377.4) | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PEAK1 | c.4975G>T p.A1659S | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIEZO2 | c.5895G>T p.W1965C | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PIK3C2B | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- PIP5K1C | c.1904C>T p.A635V | Missense Mutation (SNP) | VAF 84/476 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLCB2 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- PLEC | c.3568del p.L1190Yfs*17 (on ENST00000322810 / NM_201380.4; = p.L1080Yfs*17 on NM_000445.5) | Frame Shift Del (DEL) | VAF 65/576 reads (11%) | called by mutect2, pindel, varscan2
- PLPPR4 | c.931G>A p.G311S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2
- POTEA | c.476A>T p.N159I | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- POTEE | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 28/541 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by muse, mutect2
- POTEF | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); called by mutect2, varscan2
- PRDM13 | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); called by muse, mutect2
- PRDM13 | c.1832del p.G611Afs*107 | Frame Shift Del (DEL) | VAF 95/798 reads (12%) | called by mutect2, pindel, varscan2
- PSKH2 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PSMB1 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMC1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 52/417 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PTPN18 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2
- RALGAPB | c.1429C>A p.Q477K | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RAPGEF3 | c.853A>G p.I285V (on ENST00000389212; = p.I243V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAPSN | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RAVER2 | c.1616G>A p.S539N (on ENST00000294428 / NM_001366165.1; = p.S526N on NM_018211.4) | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2
- RBBP8NL | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 55/284 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX6 | c.505-1G>T p.X169_splice | Splice Site (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- RFX6 | c.2017T>C p.S673P | Missense Mutation (SNP) | VAF 49/377 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNASE10 | c.293G>T p.R98I | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- RNF20 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF214 | c.692C>G p.T231R | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.146); called by muse, mutect2
- RNF222 | c.356C>G p.P119R | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO3 | c.1027G>C p.V343L | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- RP1 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2
- RYR3 | c.1677G>T p.L559F | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SASH1 | c.1953G>A p.M651I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.928); called by muse, mutect2
- SELENON | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 31/560 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- SEMA3D | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SFMBT2 | c.1439C>G p.T480R | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- SH2D4B | c.806T>A p.L269H | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SHPRH | c.2007A>G p.I669M | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SI | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SKIL | c.495_496del p.C166Ffs*22 | Frame Shift Del (DEL) | VAF 24/210 reads (11%) | called by pindel, varscan2
- SLC24A3 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); called by muse, mutect2
- SLC26A8 | c.574A>T p.N192Y | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SLC2A2 | c.37A>G p.T13A | Missense Mutation (SNP) | VAF 75/583 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A10 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.156); called by muse, mutect2
- SLC7A9 | c.1074+2T>A p.X358_splice | Splice Site (SNP) | VAF 53/377 reads (14%) | called by muse, mutect2, varscan2
- SNX16 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- SPTA1 | c.5113C>A p.H1705N | Missense Mutation (SNP) | VAF 89/636 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ST6GAL2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 21/138 reads (15%) | PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ST8SIA6 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- STRA8 | c.644G>A p.R215Q (on ENST00000275764; = p.R193Q on NM_182489.2) | Missense Mutation (SNP) | VAF 50/648 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- STXBP4 | c.1287del p.K429Nfs*6 | Frame Shift Del (DEL) | VAF 25/144 reads (17%) | called by mutect2, pindel, varscan2
- SYNE1 | c.17280G>T p.E5760D (on ENST00000367255 / NM_182961.4; = p.E5689D on NM_033071.3) | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TAFA5 | c.178A>T p.T60S (on ENST00000402357 / NM_001082967.3; = p.T53S on NM_015381.7) | Missense Mutation (SNP) | VAF 62/523 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TAS2R7 | c.483G>T p.K161N | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TCF19 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TESMIN | c.633G>A p.V211= | Splice Region (SNP) | VAF 41/151 reads (27%) | called by muse, mutect2, varscan2
- TEX13A | c.1155T>A p.C385* | Nonsense Mutation (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- TF | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 113/650 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TIGAR | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 56/417 reads (13%) | called by muse, mutect2, varscan2
- TMEM38B | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM63A | c.2122A>C p.I708L | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TRIM72 | c.391-1G>T p.X131_splice | Splice Site (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- UBR7 | c.37del p.E13Sfs*41 | Frame Shift Del (DEL) | VAF 40/226 reads (18%) | called by mutect2, pindel, varscan2
- UNC5D | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- UNC80 | c.761C>A p.T254N | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2
- USH2A | c.7607T>A p.V2536E | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- USP7 | c.511A>G p.M171V | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- VAT1L | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- VWDE | c.2790del p.N931Mfs*13 | Frame Shift Del (DEL) | VAF 16/144 reads (11%) | called by mutect2, pindel, varscan2
- WASF3 | c.549del p.K183Nfs*3 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by pindel, varscan2
- WDR64 | c.2052G>C p.V684= | Splice Region (SNP) | VAF 24/170 reads (14%) | called by muse, mutect2, varscan2
- YTHDF2 | c.834G>T p.W278C | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZCCHC14 | c.834G>A p.M278I (on ENST00000268616; = p.M415I on NM_015144.3) | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- ZFHX3 | c.3388G>T p.E1130* | Nonsense Mutation (SNP) | VAF 36/451 reads (8%) | called by muse, mutect2
- ZFHX4 | c.4990C>A p.H1664N | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZMYND11 | c.680C>G p.T227S | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ZNF189 | c.754A>T p.R252W | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF480 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF804B | c.3726T>G p.H1242Q | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.277); called by muse, mutect2
- ZNFX1 | c.4319A>C p.D1440A | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.127); called by muse, mutect2
- ZPLD1 | c.859C>G p.Q287E (on ENST00000466937 / NM_001329788.1; = p.Q303E on NM_175056.2) | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ADAMTS16 | c.2458C>A p.R820= | Silent (SNP) | VAF 79/529 reads (15%) | catalogued as rs747638541, COSV56995053; called by muse, mutect2, varscan2
- BCL11B | c.1740G>T p.G580= (on ENST00000357195 / NM_001282237.2; = p.G509= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 130/588 reads (22%) | called by muse, mutect2, varscan2
- BTBD3 | c.1191C>T p.I397= | Silent (SNP) | VAF 40/260 reads (15%) | called by muse, mutect2, varscan2
- C3orf14 | c.318A>T p.A106= | Silent (SNP) | VAF 33/194 reads (17%) | called by muse, mutect2, varscan2
- CCDC168 | c.540A>C p.T180= | Silent (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- CCL22 | c.105C>T p.V35= | Silent (SNP) | VAF 54/339 reads (16%) | catalogued as COSV54659772; called by muse, mutect2, varscan2
- CEL | c.1452T>A p.S484= (on ENST00000673714; = p.S481= on NM_001807.6) | Silent (SNP) | VAF 66/384 reads (17%) | called by muse, mutect2, varscan2
- CFAP52 | c.297G>A p.K99= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as rs1260002210, COSV55343399; called by muse, mutect2, varscan2
- CHGB | c.532C>A p.R178= | Silent (SNP) | VAF 23/153 reads (15%) | catalogued as COSV66761128; called by muse, mutect2, varscan2
- CHI3L1 | c.783C>T p.F261= | Silent (SNP) | VAF 59/411 reads (14%) | catalogued as rs150868636; called by muse, mutect2, varscan2
- CHPF | c.1434C>A p.R478= | Silent (SNP) | VAF 11/274 reads (4%) | called by muse, mutect2
- CHST6 | c.765C>T p.A255= | Silent (SNP) | VAF 141/897 reads (16%) | catalogued as rs1240807684, COSV60002070; called by muse, mutect2, varscan2
- CHSY3 | c.1884C>T p.I628= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs780877726, COSV59277467; called by muse, mutect2, varscan2
- CLMN | c.2979C>T p.L993= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as rs1391916217, COSV100112343; called by muse, varscan2
- CNTNAP2 | c.2571C>A p.S857= | Silent (SNP) | VAF 29/622 reads (5%) | catalogued as rs984523547; called by muse, mutect2
- COL20A1 | c.783C>A p.A261= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV58916305; called by muse, mutect2, varscan2
- CYP2C19 | c.861G>A p.L287= | Silent (SNP) | VAF 57/269 reads (21%) | catalogued as COSV64906679; called by muse, mutect2, varscan2
- CYP2E1 | c.570C>T p.D190= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- DMPK | c.963G>T p.P321= | Silent (SNP) | VAF 28/449 reads (6%) | called by muse, mutect2
- DNAH7 | c.4218A>T p.A1406= | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- FAM131B | c.879G>T p.L293= | Silent (SNP) | VAF 50/520 reads (10%) | called by muse, mutect2
- FAM169A | c.1167G>A p.Q389= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as rs1299282572; called by muse, mutect2, varscan2
- FEZF2 | c.180C>A p.G60= | Silent (SNP) | VAF 26/167 reads (16%) | called by muse, mutect2, varscan2
- GABRA2 | c.1197G>A p.K399= | Silent (SNP) | VAF 74/707 reads (10%) | called by muse, mutect2, varscan2
- GABRG1 | c.168C>A p.A56= | Silent (SNP) | VAF 31/310 reads (10%) | catalogued as COSV54955990; called by muse, mutect2, varscan2
- GLYATL3 | c.543C>A p.I181= | Silent (SNP) | VAF 40/478 reads (8%) | catalogued as COSV64592149; called by muse, mutect2
- GPR156 | c.1518C>T p.P506= | Silent (SNP) | VAF 51/325 reads (16%) | called by muse, mutect2, varscan2
- GPR17 | c.840C>T p.H280= | Silent (SNP) | VAF 61/451 reads (14%) | catalogued as rs758362503; called by muse, mutect2, varscan2
- GRAMD1A | c.1398C>T p.G466= | Silent (SNP) | VAF 21/548 reads (4%) | called by muse, mutect2
- GRM8 | c.1839C>T p.I613= | Silent (SNP) | VAF 54/361 reads (15%) | catalogued as rs766635867, COSV58842108; called by muse, mutect2, varscan2
- HERPUD2 | c.1125A>C p.A375= | Silent (SNP) | VAF 14/237 reads (6%) | called by muse, mutect2
- HTT | c.2607G>T p.L869= | Silent (SNP) | VAF 33/176 reads (19%) | called by muse, mutect2, varscan2
- JPH2 | c.441G>T p.V147= | Silent (SNP) | VAF 71/637 reads (11%) | called by muse, mutect2, varscan2
- KCNA3 | c.60C>A p.A20= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- KCNA6 | c.1299G>T p.V433= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as rs776927383, COSV99768680; called by muse, mutect2, varscan2
- KLHL34 | c.1437G>A p.S479= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as rs747750810; called by muse, mutect2, varscan2
- LRRC1 | c.351G>T p.L117= | Silent (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2, varscan2
- MAGEB4 | c.222T>A p.A74= | Silent (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- MKI67 | c.1866C>T p.G622= | Silent (SNP) | VAF 31/419 reads (7%) | called by muse, mutect2
- MYO18B | c.3558G>A p.A1186= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as rs751761773, COSV59126688; called by muse, mutect2, varscan2
- NBEAL2 | c.7773A>G p.L2591= | Silent (SNP) | VAF 42/266 reads (16%) | called by muse, mutect2, varscan2
- NLRP7 | c.1224G>A p.L408= | Silent (SNP) | VAF 51/436 reads (12%) | catalogued as COSV60183533; called by muse, mutect2, varscan2
- NRXN1 | c.3639T>C p.H1213= | Silent (SNP) | VAF 19/388 reads (5%) | catalogued as rs1243594919; called by muse, mutect2
- OCA2 | c.285A>T p.T95= | Silent (SNP) | VAF 40/342 reads (12%) | called by muse, mutect2, varscan2
- OPN4 | c.1129C>A p.R377= | Silent (SNP) | VAF 60/284 reads (21%) | catalogued as rs147596527; called by mutect2, varscan2
- PKHD1L1 | c.1506C>A p.S502= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- POLR2D | c.9G>T p.A3= | Silent (SNP) | VAF 19/289 reads (7%) | catalogued as rs776417599; called by muse, mutect2
- PRKCB | c.336C>A p.P112= | Silent (SNP) | VAF 35/290 reads (12%) | catalogued as COSV57805403; called by muse, mutect2, varscan2
- RBM39 | c.457A>C p.R153= | Silent (SNP) | VAF 21/338 reads (6%) | called by muse, mutect2
- RIN3 | c.264C>T p.R88= | Silent (SNP) | VAF 34/216 reads (16%) | catalogued as rs936773228; called by muse, varscan2
- RPA1 | c.936G>A p.S312= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs765247029, COSV54614973; called by muse, mutect2, varscan2
- RYR2 | c.3246G>A p.G1082= | Silent (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- RYR2 | c.6201C>A p.V2067= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- S1PR1 | c.312G>A p.L104= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV59514155; called by muse, mutect2
- SCN10A | c.5124C>A p.I1708= | Silent (SNP) | VAF 63/415 reads (15%) | catalogued as rs779225765, COSV71862770; called by muse, mutect2, varscan2
- SETBP1 | c.168G>A p.E56= | Silent (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.855T>C p.R285= | Silent (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- SLC7A1 | c.1764G>C p.R588= | Silent (SNP) | VAF 31/171 reads (18%) | called by muse, mutect2, varscan2
- TAAR2 | c.975A>T p.A325= (on ENST00000367931 / NM_001033080.1; = p.A280= on NM_014626.3) | Silent (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2, varscan2
- TMEM132C | c.282G>T p.V94= | Silent (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- TRIP6 | c.66G>A p.A22= | Silent (SNP) | VAF 49/263 reads (19%) | catalogued as rs1247906820; called by muse, mutect2, varscan2
- TUBB4A | c.429G>T p.T143= | Silent (SNP) | VAF 43/488 reads (9%) | called by muse, mutect2
- UNC5B | c.1896C>T p.D632= | Silent (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- WDR49 | c.60G>A p.Q20= (on ENST00000308378 / NM_001366158.1; = p.Q361= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/276 reads (17%) | catalogued as COSV100394059; called by muse, mutect2, varscan2
- WDR72 | c.1701G>T p.P567= | Silent (SNP) | VAF 44/393 reads (11%) | catalogued as rs776018576, COSV100855347; called by muse, mutect2, varscan2
- ZNF461 | c.1688_*5del | Silent (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- ZNF543 | c.171G>T p.L57= | Silent (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- ZNF570 | c.42G>T p.V14= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- ZNF609 | c.1974C>T p.P658= | Silent (SNP) | VAF 34/218 reads (16%) | called by muse, mutect2, varscan2
- AC084879.1 | n.1138C>T | RNA (SNP) | VAF 52/415 reads (13%) | catalogued as rs984589320; called by muse, mutect2, varscan2
- ACADVL | c.138+28G>C | Intron (SNP) | VAF 27/169 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.2376+46C>A | Intron (SNP) | VAF 61/423 reads (14%) | called by muse, mutect2, varscan2
- AGAP7P | n.1526C>G | RNA (SNP) | VAF 36/1254 reads (3%) | catalogued as rs782061484; called by muse, mutect2
- ANKRD10 | c.455+5408G>T | Intron (SNP) | VAF 57/260 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.*2665G>C | 3'UTR (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- BSND | c.*33C>G | 3'UTR (SNP) | VAF 24/430 reads (6%) | called by muse, mutect2
- BTN2A1 | c.*106C>G | 3'UTR (SNP) | VAF 29/413 reads (7%) | called by muse, mutect2
- C8orf44-SGK3 | c.-121-25683T>G | Intron (SNP) | VAF 22/183 reads (12%) | called by muse, mutect2, varscan2
- CABP5 | c.-54G>T | 5'UTR (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- CNTN5 | c.55+2009G>T | Intron (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- COBL | c.1096+19795G>T | Intron (SNP) | VAF 39/191 reads (20%) | called by muse, mutect2, varscan2
- COL1A2 | c.2781+46A>T | Intron (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- CRISP2 | c.515+160G>T | Intron (SNP) | VAF 29/225 reads (13%) | called by muse, mutect2, varscan2
- FAM174A | c.*14G>A | 3'UTR (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100444603; called by muse, mutect2, varscan2
- FAM234A | c.577+408C>T | Intron (SNP) | VAF 38/232 reads (16%) | catalogued as rs746041962; called by muse, mutect2, varscan2
- FAM86C2P | n.917G>A | RNA (SNP) | VAF 70/584 reads (12%) | called by muse, mutect2
- FAM90A27P | n.982C>A | RNA (SNP) | VAF 72/370 reads (19%) | called by muse, mutect2, varscan2
- FOLH1B | n.1809G>C | RNA (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- GCSAML | c.-56-10417G>T | Intron (SNP) | VAF 39/279 reads (14%) | catalogued as COSV63575880; called by muse, mutect2, varscan2
- GREM2 | c.*739T>A | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- GSR | c.-1C>T | 5'UTR (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2
- GUCY2EP | n.312G>T | RNA (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- HGD | c.650-169G>T | Intron (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- HIBCH | c.-33C>T | 5'UTR (SNP) | VAF 40/363 reads (11%) | catalogued as rs755501645; called by muse, mutect2, varscan2
- IFT22 | chr7:101310851 A>G | 3'Flank (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- KCNT1 | c.378-14G>T | Intron (SNP) | VAF 57/268 reads (21%) | called by muse, varscan2
- LDB2 | c.891+2565A>T | Intron (SNP) | VAF 31/172 reads (18%) | called by muse, varscan2
- LILRB5 | c.1255+51C>A | Intron (SNP) | VAF 7/94 reads (7%) | catalogued as rs564734584; called by muse, mutect2
- LINC00618 | chr14:96931359 C>A | 5'Flank (SNP) | VAF 69/453 reads (15%) | called by muse, mutect2, varscan2
- MFN2 | c.2070-13C>T | Intron (SNP) | VAF 74/615 reads (12%) | called by muse, mutect2, varscan2
- MIR518D | n.73C>T | RNA (SNP) | VAF 13/174 reads (7%) | catalogued as rs151129856; called by muse, mutect2
- MUC19 | chr12:40563588 T>A | 5'Flank (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- MYH16 | n.3296C>T | RNA (SNP) | VAF 33/320 reads (10%) | catalogued as rs778246457; called by muse, mutect2, varscan2
- MYPN | c.*706G>T | 3'UTR (SNP) | VAF 90/826 reads (11%) | called by mutect2, varscan2
- NALCN | c.2193-5316C>A | Intron (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- NFIB | c.1245+4099C>T | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as rs750290208; called by muse, mutect2
- NME1 | c.229-20A>G | Intron (SNP) | VAF 48/560 reads (9%) | called by muse, mutect2
- NUMBL | c.249+37G>T | Intron (SNP) | VAF 43/244 reads (18%) | catalogued as rs755300610; called by muse, mutect2, varscan2
- OR1D4 | n.48G>C | RNA (SNP) | VAF 148/788 reads (19%) | called by muse, mutect2, varscan2
- OR2A13P | n.541C>G | RNA (SNP) | VAF 53/382 reads (14%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65752A>T | Intron (SNP) | VAF 28/468 reads (6%) | called by muse, mutect2
- PLPPR4 | c.539-83C>A | Intron (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- POU1F1 | c.*31C>A | 3'UTR (SNP) | VAF 16/160 reads (10%) | called by muse, varscan2
- PPDPFL | c.*36G>A | 3'UTR (SNP) | VAF 44/278 reads (16%) | called by muse, mutect2, varscan2
- PRSS55 | c.155-89G>T | Intron (SNP) | VAF 10/68 reads (15%) | catalogued as rs766526779; called by muse, mutect2
- PTPN6 | c.-2G>T | 5'UTR (SNP) | VAF 28/577 reads (5%) | called by muse, mutect2
- RAN | c.-488_-476del | 5'UTR (DEL) | VAF 27/183 reads (15%) | called by mutect2, pindel
- RBCK1 | c.-5G>C | 5'UTR (SNP) | VAF 55/275 reads (20%) | called by muse, mutect2, varscan2
- RNU1-5P | chr1:16871095 A>T | 5'Flank (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- SAP18 | chr13:21140562 G>T | 5'Flank (SNP) | VAF 31/199 reads (16%) | called by muse, mutect2, varscan2
- SLC22A13 | c.*1T>C | 3'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1265A>G | RNA (SNP) | VAF 103/711 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.10456G>T | RNA (SNP) | VAF 48/353 reads (14%) | catalogued as rs750475806, COSV100948262; called by muse, mutect2, varscan2
- SVIL | c.3665-1217T>C | Intron (SNP) | VAF 22/221 reads (10%) | called by muse, mutect2
- TENM3 | c.511+102135C>G | Intron (SNP) | VAF 59/397 reads (15%) | called by muse, mutect2, varscan2
- THEMIS | c.*70G>T | 3'UTR (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- THY1 | c.-33C>T | 5'UTR (SNP) | VAF 124/750 reads (17%) | called by muse, mutect2, varscan2
- WDR45B | c.-43A>T | 5'UTR (SNP) | VAF 35/474 reads (7%) | called by muse, mutect2
- WT1 | chr11:32435823 C>T | 5'Flank (SNP) | VAF 34/282 reads (12%) | catalogued as rs568055576; called by muse, mutect2, varscan2
